CCDI case PBCBZK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/e83bd3ba-f37e-49d1-bd8f-fdde6b3863c4

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Rhabdomyoma, NOS: ICD-O-3 morphology code: 8900/0; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 5.7 years (2,094 days).

Biospecimens (3 samples)
- Sample 0DODM8: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DODN0: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DODO0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
